Gene-level copy-number profile of tumor specimen TCGA-2G-AAGE-01A from TCGA case TCGA-2G-AAGE, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 21.2 years (7,753 days).
Specimen TCGA-2G-AAGE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.cea0564e-94cc-4ce5-a8f2-1119d744758a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAGE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/21ce5fbc-8ec0-4550-b920-743c56b3c68a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 29,100; copy number 3: 24,949; copy number 4: 4,112; copy number 5: 25; copy number 8: 1,061; copy number 9: 557.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAGE-01A-21D-A42X-01): tumor purity 0.82, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,643 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:94,278,680–95,324,532, 19 genes, copy number 5 (within-gene range 4–5): AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1.
- chr8:46,028,804–97,149,654, 768 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 8–9 (broad region; genes not listed).
- chr16:34,962,970–35,084,313, 6 genes, copy number 5 (within-gene range 4–5): AC135776.5, LINC02184, AC135776.1, AC135776.2, AC135776.3, CCNYL3.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
